Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A004, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A004-01A (Primary Tumor).

Sample ID #

Diagnosis:

Resected colon sample with an ulcerated, highly differentiated adenocarcinoma of the colorectal type with infiltration of the pericolic fatty tissue. Tumor-free local lymph nodes. Tumor-free colonic resection margins. Tumor-free mesenteric resection margin. In addition, a small tubular adenoma of the colonic mucous membrane with mild dysplasia (synonymous: mild intraepithelial neoplasia).

Stage of tumor: pT3 pN0 (0/32) MX; G1, L0, V0, R0)

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Sigmoid colon (w/ COCF) C18.7 for 3/29/11

ICD-0 Discrepancy		☒
Reviewed (initials)	for 3/29/11	

Source: NCI Genomic Data Commons file 0550ab5e-51d8-47bb-a56f-70cb4ae93e05 (TCGA-AA-A004.A4C2CE68-97FC-4EA6-AAD0-75F0B0EC3AD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).